Gene-level copy-number profile of tumor specimen ALCH-B4B9-TTP1-A from ALCHEMIST case ALCH-B4B9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.5 years (26,112 days).
Specimen ALCH-B4B9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 79ff10e7-7fd4-4b35-b4ba-edd9c9335fe9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4B9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/dfe648b9-615f-4d1c-816d-4c9e17d771eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 539; copy number 1: 18,836; copy number 2: 32,314; copy number 3: 6,570; copy number 4: 583; copy number 21: 26; copy number 28: 2; copy number 41: 3; copy number 49: 2; copy number 50: 27; copy number 81: 2.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,048,426–130,182,750, 8 genes (within-gene range 0–2): CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P, MED15P9, CCDC74B, SMPD4.
- chr3:49,873,347–49,903,873, 3 genes (within-gene range 0–1): ACTBP13, MST1R, AC105935.2.
- chr3:50,599,879–50,649,291, 3 genes: AC096920.1, CISH, MAPKAPK3.
- chr5:160,195,744–160,204,826, 1 gene (within-gene range 0–1): FABP6-AS1.
- chr5:176,526,712–176,595,974, 4 genes (within-gene range 0–1): RNF44, CDHR2, RN7SL684P, Y_RNA.
- chr6:39,299,001–39,322,968, 2 genes: KCNK17, KCNK16.
- chr6:57,919,784–57,930,291, 1 gene: GUSBP4.
- chr6:57,937,458–57,939,015, 1 gene: POM121L14P.
- chr7:66,070,904–66,094,697, 2 genes (within-gene range 0–2): AC068533.1, ASL.
- chr7:140,241,870–140,242,032, 1 gene: RNU1-58P.
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–1): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr8:20,246,165–20,303,963, 1 gene (within-gene range 0–1): LZTS1.
- chr9:63,703,065–63,720,441, 2 genes: AL591438.2, CDRT15P7.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr11:73,238,975–73,242,335, 1 gene: AP002761.4.
- chr11:76,186,325–76,216,025, 3 genes (within-gene range 0–1): WNT11, AP000785.1, LINC02761.
- chr11:77,066,961–77,126,155, 2 genes: CAPN5, OMP.
- chr11:123,597,946–123,599,452, 1 gene (within-gene range 0–1): SF3A3P2.
- chr11:133,840,631–134,319,564, 17 genes (within-gene range 0–1): SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1.
- chr12:31,105,105–31,106,830, 1 gene: AC008013.3.
- chr13:95,310,830–95,336,201, 2 genes: RNY3P8, RNY4P27.
- chr14:102,501,676–102,539,726, 3 genes (within-gene range 0–1): RNU6-244P, ANKRD9, MIR4309.
- chr15:25,180,497–25,225,284, 25 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:50,292,616–50,292,675, 1 gene (within-gene range 0–1): MIR6771.
- chr17:3,577,955–3,663,103, 5 genes (within-gene range 0–1): AC027796.5, SHPK, AC027796.2, CTNS, AC027796.4.
- chr17:16,342,534–16,492,193, 13 genes (within-gene range 0–1): CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:48,949,361–48,956,753, 2 genes: RNU1-42P, AC091133.2.
- chr20:407,498–432,139, 1 gene: RBCK1.
- chr20:45,293,445–45,308,529, 1 gene (within-gene range 0–1): MATN4.
- chr21:43,414,483–43,427,131, 1 gene: SIK1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 62 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,612,899–71,252,577, 62 genes, copy number 21–81 (within-gene range 2–81) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,408. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
